Somatic mutation profile of tumor specimen BA2875D (aliquot aq-BA2875D) from BEATAML1.0 case 2266, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.3 years (24,578 days).
Specimen BA2875D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40f33699-c156-46d7-811f-ce593687f017.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2958D (Solid Tissue Normal), aliquot aq-BA2958D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4bacb505-a0b9-44a0-9ec2-12dd3990cdda

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SRSF2 | c.284C>G p.P95R | Missense Mutation (SNP) | VAF 14/101 reads (14%) | hotspot (GDC flag); SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as rs751713049, CM1511359, COSV57969809, COSV57969816, COSV57969830; called by muse, mutect2, varscan2
- ANKRD63 | c.265A>C p.S89R | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (0.28); called by muse, mutect2
- UTP14C | c.885C>A p.S295R | Missense Mutation (SNP) | VAF 22/420 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SERPINB13 | chr18:63604012 A>G | 3'Flank (SNP) | VAF 37/139 reads (27%) | called by muse, mutect2, varscan2
